Somatic mutation profile of tumor specimen MP2PRT-PAVDAP-TMP1-A (aliquot MP2PRT-PAVDAP-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVDAP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (748 days).
Specimen MP2PRT-PAVDAP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69130e4e-79c7-4671-ae45-7f0f50ee5833.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDAP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDAP-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b837547-6df5-49e1-9c6b-a224605fc5f8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC8 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 135/592 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs397515417, CM128299, COSV65265074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 64/129 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DDX52 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 186/608 reads (31%) | catalogued as rs576442612; called by muse, mutect2, varscan2
- METTL7B | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 172/351 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1363716699, COSV57694837; called by muse, mutect2, varscan2
- ZFR2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.176); catalogued as rs374607467; called by muse, mutect2
- ADGRG4 | c.4261T>C p.S1421P | Missense Mutation (SNP) | VAF 163/666 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC4 | c.759T>A p.Y253* | Nonsense Mutation (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- NACC1 | c.1497C>T p.I499= | Silent (SNP) | VAF 186/378 reads (49%) | catalogued as rs200782466; called by muse, mutect2, varscan2
- TENM4 | c.1995C>T p.P665= | Silent (SNP) | VAF 105/257 reads (41%) | called by muse, mutect2, varscan2
